FM case AD4670 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/5ce70c0a-da37-451b-a642-f69c52f89caf

Male, 69.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the rectum; primary biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
